Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7793, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7793-01A (Primary Tumor).

FINAL DIAGNOSIS:

PROSTATE, BILATERAL SEMINAL VESICLES, AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE WITH FOCAL EXTRACELLULAR MUCIN, GLEASON SCORE 3 + 4 = 7. GLEASON PATTERN 4 COMPONENT COMPRISES APPROXIMATELY 25% OF THE EXAMINED TUMOR VOLUME.
- B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES (APEX THROUGH MID) AND HAS A MAXIMAL TUMOR DIAMETER OF 0.8 CM IN A HISTOLOGIC SECTION
- C. CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. CARCINOMA IS CONFINED TO THE PROSTATE GLAND WITH NO EXTRACAPSULAR EXTENSION IDENTIFIED.
- E. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE BENIGN.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- G. NO PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS IDENTIFIED.
- J. NON-NEOPLASTIC PROSTATE TISSUE WITH FOCAL ACUTE INFLAMMATION AND FOCAL GLANDULAR ATROPHY.
- K. PATHOLOGIC STAGE: pT2c NX MX.
- L. HISTOLOGIC GRADE: G3-4 (SEE SYNOPTIC).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 3.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	25%
WEIGHT OF PROSTATE:	42.01gm
TUMOR SIZE:	Maximum dimension: 0.8 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	0
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

PATIENT HISTORY:

The patient is a [REDACTED] with a serum PSA value of 3.0 ng/mL. He had a prostate needle biopsy performed elsewhere reported as prostatic adenocarcinoma, Gleason score 3+4=7 in the right lateral apex and left lateral apex. The patient's father had prostate cancer. The patient also has a history of septorhinoplasty, right knee repair, and vasectomy.

Diagnosis: Prostate cancer

Postop Diagnosis: Prostate cancer

Surgical Procedure: PROSTATECTOMY LAPAROSCOPIC ROBOTIC ASSISTED

Surgical Procedure: ROBOTIC ASSISTED SURGERY

Reason previous hospitalization/surgery = Repair deviated septum

Reason previous hospitalization/surgery = Vasectomy

Reason previous hospitalization/surgery = Right knee surgery for gunshot wound

Cardiovascular medical history = Other: high cholesterol

Respiratory medical history = Sleep apnea

Gastrointestinal medical history = GERD

Reproductive medical history = [REDACTED]

Skin condition medical history = [REDACTED]

Oncology medical history = Prostate cancer

Reaction to anesthesia = No

Reaction to blood/blood products? = Never received blood/blood products

Airway issues? = No

Source: NCI Genomic Data Commons file bfef18d6-ddb1-4922-8b73-b99355c1a4c7 (TCGA-EJ-7793.C9D3D69C-F362-454F-A8FF-CBDA4D713C41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).